CCDI case PBCDVA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/279c32ee-0955-4c21-91f0-0a9751ec1eb9

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Carcinoid tumor of uncertain malignant potential: ICD-O-3 morphology code: 8240/1; Tissue or organ of origin: Appendix; Age at diagnosis: 13.9 years (5,068 days).

Biospecimens (2 samples)
- Sample 0DPMQT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPMS4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
